Somatic mutation profile of tumor specimen 0DWNTV from CCDI case PBCPJK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,441 days).
Specimen 0DWNTV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f868632d-badc-47d2-914a-635aa55f8729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e517b47f-8d99-4c38-aee4-84b8094bb0c7

The open-access MAF lists 31 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, 5'UTR 3, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, Translation Start Site 1, 3'UTR 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.1997del p.T666Sfs*6 (on ENST00000326195 / NM_001025091.2; = p.T628Sfs*6 on NM_001090.3) | Frame Shift Del (DEL) | VAF 242/599 reads (40%) | catalogued as COSV100400757; called by mutect2, pindel, varscan2
- CLPP | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 220/459 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs759816700, COSV55534196; called by muse, mutect2, varscan2
- GRWD1 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 281/616 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs773302363; called by muse, mutect2, varscan2
- ITGAX | c.1598G>C p.G533A | Missense Mutation (SNP) | VAF 26/702 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1161297741; called by muse, mutect2
- KATNAL2 | c.490G>A p.G164S (on ENST00000356157 / NM_001353899.1; = p.G92S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/620 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs748167860; called by muse, mutect2
- KDM6A | c.334+1G>C p.X112_splice | Splice Site (SNP) | VAF 73/85 reads (86%) | catalogued as COSV65042452; called by muse, mutect2, varscan2
- SYNE1 | c.25036C>T p.R8346C (on ENST00000367255 / NM_182961.4; = p.R8298C on NM_033071.3) | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs543351996; called by muse, mutect2
- ADGB | c.2404A>T p.N802Y | Missense Mutation (SNP) | VAF 118/513 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CNKSR3 | c.261A>T p.K87N | Missense Mutation (SNP) | VAF 24/582 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ERMARD | c.1314dup p.Q439Tfs*6 | Frame Shift Ins (INS) | VAF 306/796 reads (38%) | called by mutect2, pindel, varscan2
- KDM6B | c.408C>G p.Y136* | Nonsense Mutation (SNP) | VAF 294/315 reads (93%) | called by muse, mutect2, varscan2
- MAN1B1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 244/525 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MINK1 | c.2202C>G p.N734K | Missense Mutation (SNP) | VAF 309/338 reads (91%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NR2C2 | c.552G>T p.M184I (on ENST00000393102; = p.M203I on NM_003298.5) | Missense Mutation (SNP) | VAF 14/518 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.251); called by muse, mutect2
- SPATA31D3 | c.2689C>A p.Q897K | Missense Mutation (SNP) | VAF 171/819 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TPBGL | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TRIM7 | c.1487C>G p.P496R | Missense Mutation (SNP) | VAF 135/540 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZCCHC8 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 168/1030 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ZNF512 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 16/511 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- C12orf40 | c.282A>G p.T94= | Silent (SNP) | VAF 102/537 reads (19%) | catalogued as rs1173197712; called by muse, mutect2, varscan2
- FUOM | c.75G>T p.G25= | Silent (SNP) | VAF 181/410 reads (44%) | called by muse, mutect2, varscan2
- MUC12 | c.8664C>T p.T2888= (on ENST00000379442; = p.T2745= on NM_001164462.1) | Silent (SNP) | VAF 137/4007 reads (3%) | called by muse, mutect2
- OR10H3 | c.213G>A p.E71= | Silent (SNP) | VAF 31/622 reads (5%) | catalogued as COSV59944098; called by muse, mutect2
- OR2Z1 | c.123C>A p.G41= | Silent (SNP) | VAF 28/586 reads (5%) | catalogued as rs566366007, COSV60691678; called by muse, mutect2
- RABGEF1 | c.1159T>C p.L387= (on ENST00000439720 / NM_001287061.2; = p.L374= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 66/880 reads (8%) | called by muse, mutect2
- RNF111 | c.2895C>T p.H965= (on ENST00000557998 / NM_001270530.1; = p.H957= on NM_017610.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/270 reads (41%) | called by muse, mutect2, varscan2
- BCL7A | c.-84C>G | 5'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2
- C12orf42 | c.*23C>T | 3'UTR (SNP) | VAF 32/318 reads (10%) | catalogued as rs776355830; called by muse, mutect2
- FLYWCH1 | c.-6C>T | 5'UTR (SNP) | VAF 38/196 reads (19%) | catalogued as rs1246998875; called by muse, mutect2, varscan2
- GDAP1 | c.-11C>T | 5'UTR (SNP) | VAF 36/998 reads (4%) | called by muse, mutect2
- GRIA2 | c.*3+55C>T | Intron (SNP) | VAF 169/415 reads (41%) | catalogued as rs1218896553, COSV99646098; called by muse, mutect2, varscan2
